Gene-level copy-number profile of tumor specimen HTMCP-03-06-02089-01B from CGCI case HTMCP-03-06-02089, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 41.8 years (15,269 days).
Specimen HTMCP-03-06-02089-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 773be600-3bfb-4c56-bc18-541692870f1c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02089-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/549a489a-520a-47b7-bfb6-96aa0048efef

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 5,192; copy number 2: 40,275; copy number 3: 11,128; copy number 4: 1,514; copy number 5: 65; copy number 6: 113; copy number 7: 3; copy number 8: 70; copy number 9: 28; copy number 12: 1; copy number 18: 2; copy number 26: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:91,747,940–91,748,986, 1 gene: KMT5AP2.
- chr2:140,992,543–141,208,376, 3 genes (within-gene range 0–2): Y_RNA, RNU6-904P, RPS16P3.
- chr21:44,133,610–44,210,114, 1 gene (within-gene range 0–18): GATD3A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 250 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,297,264–89,600,680, 5 genes, copy number 5: IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr6:60,281,444–60,546,660, 1 gene, copy number 7: AC244258.1.
- chr7:38,239,580–38,249,572, 1 gene, copy number 5: TRGC2.
- chr7:38,257,879–38,340,998, 14 genes, copy number 5: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes, copy number 5 (within-gene range 3–5): TRGV5P, TRGV5.
- chr7:63,632,608–63,636,617, 1 gene, copy number 26: AC006015.1.
- chr7:128,912,732–128,914,063, 1 gene, copy number 6: AC025594.1.
- chr9:138,129,399–138,177,433, 3 genes, copy number 5 (within-gene range 2–5): AL591424.1, IL9RP1, TUBBP5.
- chr16:15,125,242–15,154,564, 2 genes, copy number 9 (within-gene range 4–9): PKD1P6, MIR6511B2.
- chr20:30,214,765–30,403,384, 8 genes, copy number 5: CFTRP3, LINC01597, AL121762.1, AL121762.2, Y_RNA, FAM242A, FRG1BP, MLLT10P1.
- chr20:31,257,664–36,863,538, 208 genes, copy number 6–9 (broad region; genes not listed).
- chr21:44,107,373–44,131,181, 1 gene, copy number 12: PWP2.
- chr21:44,172,169–44,207,399, 3 genes, copy number 7–18: AP001056.2, AP001056.1, AP001057.1.

Autosomal genes at a single copy (total copy number 1): 5,168. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
